Gene-level copy-number profile of tumor specimen MP2PRT-PAUBZC-TMP1-A from MP2PRT case MP2PRT-PAUBZC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,015 days).
Specimen MP2PRT-PAUBZC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56d29fc1-5197-4338-bba4-72dfc7276ce7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUBZC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/fb6bdb8e-be84-4a74-9890-ddc7dd55d557

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 175; copy number 1: 4,203; copy number 2: 53,588; copy number 3: 916.

Homozygous deletions (total copy number 0; autosomes only): 175 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,085,177–89,085,787, 1 gene (within-gene range 0–1): IGKV3-15.
- chr2:89,134,975–89,254,015, 13 genes (within-gene range 0–1): IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr14:22,438,547–22,513,998, 42 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29.
- chr14:105,851,705–106,142,577, 54 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr14:106,482,435–106,631,653, 25 genes (within-gene range 0–2): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47, IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60.
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–2): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr20:10,435,305–10,636,829, 2 genes (within-gene range 0–2): SLX4IP, AL035456.1.
- chr22:22,730,725–22,896,111, 29 genes: AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
